Somatic mutation profile of tumor specimen TCGA-S9-A6WE-01A (aliquot TCGA-S9-A6WE-01A-12D-A33T-08) from TCGA case TCGA-S9-A6WE, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 34.2 years (12,488 days).
Specimen TCGA-S9-A6WE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab0d1c80-27b4-49ac-ab71-430f636aceae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WE-10A (Blood Derived Normal), aliquot TCGA-S9-A6WE-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/855ec1fc-b031-4e56-b91b-3519e5999585

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 40/70 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344635105, COSV50573658; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 66/154 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- CLIP1 | c.2867+1G>A p.X956_splice (on ENST00000620786 / NM_001247997.1; = p.X945_splice on NM_002956.2) | Splice Site (SNP) | VAF 32/87 reads (37%) | catalogued as COSV100212503; called by muse, mutect2, varscan2
- KAT6B | c.3485A>G p.N1162S | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as rs1340858723, COSV99769304; called by muse, mutect2, varscan2
- PDE2A | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100558511; called by muse, mutect2, varscan2
- PIKFYVE | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100011630; called by muse, mutect2, varscan2
- TMX4 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776435098, COSV55682204; called by muse, mutect2, varscan2
- ANKRD30A | c.282_285del p.D94Efs*16 (on ENST00000611781; = p.D38Efs*16 on NM_052997.2) | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- MYH14 | c.5681_5683del p.L1894del | In Frame Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel
- VWCE | c.716del p.N239Tfs*126 | Frame Shift Del (DEL) | VAF 44/150 reads (29%) | called by mutect2, pindel, varscan2
- EXPH5 | c.414T>C p.T138= | Silent (SNP) | VAF 86/214 reads (40%) | catalogued as COSV99762376; called by muse, mutect2, varscan2
- PPIC | c.489T>C p.F163= | Silent (SNP) | VAF 65/144 reads (45%) | catalogued as COSV100120653; called by muse, varscan2
- ZFYVE26 | c.765G>A p.R255= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100720741; called by muse, mutect2, varscan2
